Gene-level copy-number profile of tumor specimen ALCH-ADWH-TTP1-A from ALCHEMIST case ALCH-ADWH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.8 years (22,924 days).
Specimen ALCH-ADWH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 26dabcca-804f-47d4-9938-cc5da32e5b95.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADWH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/15733937-59fc-48d4-bd70-45789d999d1e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 148; copy number 1: 8,721; copy number 2: 49,080; copy number 3: 539; copy number 4: 56; copy number 5: 151; copy number 6: 42; copy number 7: 95; copy number 9: 25; copy number 10: 18; copy number 12: 35.

Homozygous deletions (total copy number 0; autosomes only): 140 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:916,865–965,719, 4 genes: LINC02593, SAMD11, NOC2L, KLHL17.
- chr1:6,460,786–6,466,175, 1 gene (within-gene range 0–2): TNFRSF25.
- chr1:19,072,110–19,075,511, 1 gene (within-gene range 0–2): AL137127.1.
- chr1:109,249,539–109,283,186, 2 genes: CELSR2, PSRC1.
- chr5:1,877,413–1,887,236, 2 genes: IRX4, IRX4-AS1.
- chr7:45,816,216–45,843,740, 4 genes: CICP20, AC096582.1, AC096582.2, RNU6-326P.
- chr7:73,735,038–73,738,867, 2 genes: ABHD11-AS1, ABHD11.
- chr8:22,089,150–22,133,384, 3 genes: FAM160B2, NUDT18, HR.
- chr9:130,902,438–130,945,520, 2 genes: FIBCD1, AL161733.1.
- chr10:84,173,801–84,185,294, 1 gene: C10orf99.
- chr11:44,260,440–44,310,139, 1 gene: ALX4.
- chr12:57,128,483–57,251,188, 8 genes (within-gene range 0–2): LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3.
- chr12:122,167,738–122,203,471, 2 genes: LRRC43, IL31.
- chr12:122,834,453–122,862,961, 1 gene: HIP1R.
- chr12:131,828,393–131,851,783, 1 gene: MMP17.
- chr13:113,324,163–113,453,524, 4 genes: GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1.
- chr14:102,539,644–102,539,726, 1 gene: MIR4309.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr15:25,180,497–25,225,284, 25 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:41,828,095–41,894,053, 5 genes (within-gene range 0–1): JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr15:76,993,359–77,037,475, 1 gene: PSTPIP1.
- chr15:84,389,729–84,421,837, 6 genes: AC243562.2, RN7SL417P, AC243562.1, DNM1P51, CSPG4P5, UBE2Q2P11.
- chr16:15,094,411–15,154,564, 6 genes (within-gene range 0–2): AC139256.1, NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA.
- chr16:58,025,754–58,046,901, 1 gene: MMP15.
- chr16:68,367,325–68,370,262, 1 gene (within-gene range 0–2): AC099521.2.
- chr16:75,204,103–75,268,053, 5 genes: CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3.
- chr17:142,789–386,254, 5 genes (within-gene range 0–1): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1.
- chr17:1,934,677–2,025,334, 4 genes: RTN4RL1, AC099684.2, AC099684.1, AC099684.3.
- chr17:17,504,005–17,591,708, 4 genes (within-gene range 0–1): AC020558.6, PEMT, AC020558.2, RNU6-468P.
- chr17:39,665,349–39,670,475, 2 genes: TCAP, PNMT.
- chr17:75,827,225–75,844,552, 1 gene: UNC13D.
- chr17:81,539,885–81,553,961, 1 gene: FAAP100.
- chr18:12,407,896–12,432,238, 1 gene: PRELID3A.
- chr19:17,152,588–17,219,829, 4 genes (within-gene range 0–1): AC020913.1, AC020913.3, AC020913.2, USE1.
- chr19:19,512,418–19,536,076, 3 genes (within-gene range 0–1): TSSK6, NDUFA13, AC011448.1.
- chr19:45,764,785–45,815,308, 7 genes: SIX5, AC074212.1, DM1-AS, DMPK, AC011530.1, DMWD, RSPH6A.
- chr19:50,555,370–50,557,969, 1 gene (within-gene range 0–1): AC008743.1.
- chr20:3,227,417–3,245,382, 2 genes: SLC4A11, AL109976.1.
- chr22:45,875,932–45,977,162, 3 genes: BX324167.2, BX324167.1, WNT7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 366 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,846,097–143,846,504, 1 gene, copy number 6: AC239798.2.
- chr7:135,853–155,465, 2 genes, copy number 5: AC093627.5, AC093627.4.
- chr12:38,532,895–43,054,386, 61 genes, copy number 5 (broad region; genes not listed).
- chr12:57,431,116–70,434,292, 271 genes, copy number 5–12 (broad region; genes not listed).
- chr12:79,773,563–79,935,460, 1 gene, copy number 7 (within-gene range 2–7): PPP1R12A.
- chr12:79,823,778–81,759,553, 26 genes, copy number 6–7: AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1.
- chr19:1,259,384–1,274,880, 2 genes, copy number 6: CIRBP, CIRBP-AS1.
- chr22:21,341,595–21,358,067, 2 genes, copy number 9: PPP1R26P5, LINC01651.

Autosomal genes at a single copy (total copy number 1): 5,893. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
